Somatic mutation profile of tumor specimen C3L-03407-01 (aliquot CPT0190360007) from CPTAC case C3L-03407, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 57.3 years (20,944 days).
Specimen C3L-03407-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27105521-e3de-47b3-9d17-22d10a4b8536.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03407-31 (Blood Derived Normal), aliquot CPT0191160002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c78963f-b340-40e5-9808-e1df6c8ff737

The open-access MAF lists 61 somatic variants for this specimen: 41 protein-altering or splice-affecting, 15 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 15, Splice Site 4, Intron 4, Nonsense Mutation 3, In Frame Del 2, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1138_1140del p.L380del (on ENST00000521381 / NM_181523.3; = p.L110del on NM_181504.4) | In Frame Del (DEL) | VAF 4/24 reads (17%) | hotspot (GDC flag); called by mutect2, pindel
- CADPS | c.2812G>C p.E938Q | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.339); catalogued as rs1209799795, COSV51882081; called by muse, mutect2, varscan2
- FLG | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 85/531 reads (16%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.94); catalogued as rs749798893; called by muse, mutect2, varscan2
- FOXO4 | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 44/256 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.202); catalogued as COSV58575503; called by muse, mutect2, varscan2
- KIR3DL2 | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 48/336 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs745524198, COSV99551998; called by muse, mutect2, varscan2
- LGALS4 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 41/392 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.244); catalogued as rs566295391, COSV57044713; called by muse, mutect2, varscan2
- LRRC74B | c.339C>A p.D113E | Missense Mutation (SNP) | VAF 49/358 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.287); catalogued as rs781516068; called by muse, mutect2, varscan2
- OR5D16 | c.391C>A p.P131T | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65721487, COSV65723136; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 42/309 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs549183815, COSV99623683; called by muse, mutect2, varscan2
- SCIN | c.1881+3_1881+6del p.X627_splice (on ENST00000297029 / NM_001112706.3; = p.X380_splice on NM_033128.3) | Splice Site (DEL) | VAF 12/118 reads (10%) | catalogued as rs1432618611; called by mutect2, pindel
- SDK2 | c.1552G>A p.G518R | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs768271261; called by muse, mutect2, varscan2
- SETD2 | c.4213A>T p.K1405* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as COSV57431286, COSV57452515; called by muse, mutect2
- SUCO | c.3266-2A>G p.X1089_splice | Splice Site (SNP) | VAF 8/64 reads (13%) | catalogued as COSV55266659; called by mutect2, varscan2
- TBXAS1 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 30/290 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs143035930; called by muse, mutect2, varscan2
- THBS1 | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 55/277 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.063); catalogued as rs747214338, COSV52953191, COSV99527684; called by muse, mutect2, varscan2
- TP53 | c.339_341del p.F113del | In Frame Del (DEL) | VAF 30/184 reads (16%) | catalogued as rs764486868; called by pindel, varscan2
- ACACA | c.1978-1G>A p.X660_splice | Splice Site (SNP) | VAF 64/454 reads (14%) | called by muse, mutect2, varscan2
- ACTN3 | c.806C>A p.A269E | Missense Mutation (SNP) | VAF 31/230 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- CACNA1F | c.1408C>T p.L470F | Missense Mutation (SNP) | VAF 56/323 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- CDKL5 | c.589G>T p.V197L | Missense Mutation (SNP) | VAF 53/335 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- EXOC6B | c.632A>G p.K211R | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- FLG2 | c.2494G>A p.G832S | Missense Mutation (SNP) | VAF 77/433 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- GLT8D2 | c.865C>A p.H289N | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- GLYCTK | c.1177G>C p.E393Q | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ISLR2 | c.1051G>T p.G351C | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LCE3A | c.148A>C p.S50R | Missense Mutation (SNP) | VAF 93/684 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- LMO7 | c.913C>T p.Q305* (on ENST00000357063; = p.Q320* on NM_005358.5) | Nonsense Mutation (SNP) | VAF 13/99 reads (13%) | called by muse, mutect2, varscan2
- LRRC9 | c.2069C>T p.T690I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- MAN2B1 | c.421G>C p.D141H | Missense Mutation (SNP) | VAF 65/519 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- MSH4 | c.722A>G p.Q241R | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NLRP13 | c.1779_1782del p.N593Kfs*3 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | called by pindel, varscan2
- OR4D5 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PACS1 | c.978+1G>A p.X326_splice | Splice Site (SNP) | VAF 28/231 reads (12%) | called by muse, varscan2
- PLA2R1 | c.4006C>T p.Q1336* | Nonsense Mutation (SNP) | VAF 27/129 reads (21%) | called by muse, mutect2, varscan2
- PTPRC | c.3131G>T p.G1044V | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- SLFN5 | c.2250G>T p.W750C | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- SPDEF | c.252G>C p.E84D | Missense Mutation (SNP) | VAF 53/297 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPRR2F | c.35G>A p.C12Y | Missense Mutation (SNP) | VAF 94/518 reads (18%) | PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- TRIML2 | c.735A>T p.R245S | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- USP51 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 89/508 reads (18%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZMYND15 | c.1518C>G p.N506K (on ENST00000433935 / NM_001136046.3; = p.N467K on NM_032265.2) | Missense Mutation (SNP) | VAF 26/255 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- ADAMTS15 | c.2094C>T p.F698= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as rs267602783, COSV54503735; called by muse, mutect2
- ATP10B | c.825C>A p.T275= | Silent (SNP) | VAF 53/308 reads (17%) | called by muse, mutect2, varscan2
- CCNT2 | c.1464C>T p.I488= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as rs149104621; called by muse, mutect2, varscan2
- CLEC14A | c.972C>T p.D324= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV100643602, COSV60562405; called by muse, mutect2, varscan2
- FAM186A | c.495G>A p.T165= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as rs1202336628, COSV100525377, COSV59249954; called by muse, mutect2
- KCNT2 | c.337T>C p.L113= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs766361678; called by muse, mutect2, varscan2
- MYOCD | c.543C>T p.D181= | Silent (SNP) | VAF 35/216 reads (16%) | catalogued as rs368720240, COSV58497356; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NXPE2 | c.873C>T p.N291= | Silent (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2, varscan2
- PCDHB16 | c.2253C>T p.Y751= | Silent (SNP) | VAF 43/361 reads (12%) | catalogued as rs564789192, COSV53369981; called by muse, mutect2, varscan2
- RNF20 | c.939G>T p.L313= | Silent (SNP) | VAF 23/177 reads (13%) | called by muse, mutect2, varscan2
- SAFB2 | c.2580C>T p.R860= | Silent (SNP) | VAF 32/301 reads (11%) | catalogued as rs374459619; called by muse, mutect2, varscan2
- SCMH1 | c.1824G>A p.Q608= (on ENST00000326197 / NM_001031694.2; = p.Q539= on NM_012236.4) | Silent (SNP) | VAF 37/225 reads (16%) | called by muse, mutect2, varscan2
- STAC | c.894A>G p.P298= | Silent (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- UBR4 | c.4821G>A p.T1607= | Silent (SNP) | VAF 29/193 reads (15%) | catalogued as rs746263411; called by muse, mutect2, varscan2
- UMOD | c.1795C>T p.L599= | Silent (SNP) | VAF 33/265 reads (12%) | catalogued as rs960569406; called by muse, mutect2, varscan2
- AC125421.1 | n.325-214C>T | Intron (SNP) | VAF 30/330 reads (9%) | catalogued as rs773475653; called by muse, mutect2
- HBE1 | c.-267+102110A>G | Intron (SNP) | VAF 37/222 reads (17%) | called by muse, mutect2, varscan2
- OR7D1P | n.693C>T | RNA (SNP) | VAF 25/237 reads (11%) | catalogued as rs765495943; called by muse, mutect2
- SNTB1 | c.789-22337C>G | Intron (SNP) | VAF 20/144 reads (14%) | called by muse, mutect2, varscan2
- ZNF211 | c.218-656G>A | Intron (SNP) | VAF 34/117 reads (29%) | called by muse, mutect2, varscan2
